Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UJ-01A (Primary Tumor).

[page 1 of 2]
IIIIA Discrepancy		☒
Prior Pregnancy History		☒
Review Initials	RB	
W	5/1/11	

105-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 /w 5/1/11

Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

cc: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

History/Clinical Dx: Endometrial carcinoma

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

A: Uterus, cervix

B: Right adnexa and left adnexa

DIAGNOSIS:

A,B. Uterus, cervix, tubes and ovaries:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:

Hysterectomy and bilateral salpingoophorectomy

Histologic type:

Endometrioid

Histologic grade(FIGO):

Grade 1

Nuclear grade:

1

Tumor size:

1.6 x 1.2 cm in area, 0.7 cm in thickness

Extent of invasion:

No definite invasion identified

Lympho/vascular invasion:

Not identified

Serosa:

Free of involvement

Parametrium:

Free of involvement

Cervical involvement:

Free of involvement

Right adnexa:

Free of tumor

Left adnexa:

Brenner tumor

Other findings:

One intramural leiomyoma

Staging information:

T1a NX MX

Intraoperative Consultation:

A. Frozen Section Interpretation: Endometrial adenocarcinoma with no evidence of myometrial invasion.

Disclaimer Statement:

The following statement may be applicable to some of the reagents/instruments used in developing the above report. This test was developed and its performance characteristics determined by [REDACTED] has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that certain reagents/instruments require approval for use in clinical research. This test is used for clinical purposes. It should not be regarded as a substitute for clinical research. The laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

Gross Description

A. Received: Fresh, unopened, intact is a single piece of soft tan to pink tissue
Labeled: Uterus, cervix
Weight: 55 grams
Size: 7.2 x 3.5 x 3.2 cm
Appearance
Tumor
Location: Right lateral wall of uterus
Configuration: Polypoid, fungating, soft tan to pink
Size: 1.6 x 1.2 x 0.7 cm
Depth of invasion: Superficial, does not appear to invade the myometrium
Invasion of contiguous structures: None grossly identified
Distance from margins: 3.7 cm from the cervical margin
Cervix: Smooth, shiny, white, grossly unremarkable
Endometrium: 0.2 cm in thickness, smooth, shiny, tan with areas of hemorrhage and mucoid material
Myometrium: 2.1 cm in thickness, no areas of adenomyosis are grossly identified. There is one myoma grossly identified, 1.5 x 1.2 x 0.7 cm
Special studies: Pending
Other: None

KEY TO CASSETTES:

A1	-	Frozen section
A2	-	Cervix
A3	-	Lower uterine segment, full thickness
A4-A5	-	Tumor with underlying myometrium, full thickness
A6-A9	-	Endo/myometrium
A10	-	Left and right parametrium (left inked blue) myoma
A11	-	Additional myometrium

- B. Received in formalin labeled "right adnexa and left adnexa" are two pieces of unoriented soft tan to white tissue, 12 grams, aggregating up to 5.0 x 3.2 x 1.9 cm. The specimens are unoriented. The left adnexa is inked blue, with the left ovary measuring 2.0 x 1.0 x 1.0 cm, and appears grossly unremarkable. The left tube measures 2.1 x 0.5 x 0.4 cm, and appears grossly unremarkable with no paratubal cystic structures grossly identified. The right ovary measures 2.2 x 1.2 x 0.5 cm, and appears grossly unremarkable. The right tube measures 3.5 x 0.5 x 0.5 cm and is grossly unremarkable with no paratubal cystic structures grossly identified. The cut surface of the left ovary is white, homogenous with no cystic structures. The right ovary shows a homogenous white cut surface with no cystic structures grossly identified. Representative sections are submitted in two cassettes, with left adnexa submitted in cassette B1 (inked blue) and right adnexa (B2).

Microscopic Description

The microscopic findings support the above diagnosis.

Source: NCI Genomic Data Commons file 408cbdb2-6ce3-41f2-84f0-c8361c833c4a (TCGA-BS-A0UJ.DEE9AA2E-DA73-4074-9588-C75DDEC4D29B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).